Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8158, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8158-01A (Primary Tumor).

[page 1 of 2]
NAME: [REDACTED]

PATH. NO: [REDACTED]

AGE/SEX: [REDACTED] F

DOB: [REDACTED]

MED. REC. NO:

SURGERY DATE: [REDACTED]

RECEIVE DATE: [REDACTED]

PATIENT PHONE NO.:

PHYSICIAN: [REDACTED]

COPY TO:

[REDACTED] TCGA-DU-8158

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSIES: ASTROCYTOMA WITH ATYPICAL FEATURES.
- B. BRAIN, LEFT FRONTAL, EXCISION: ASTROCYTOMA WITH ANAPLASTIC FEATURES. MIB-1 PROLIFERATION INDEX: 2% TO 3%.
- C. BRAIN, LEFT FRONTAL, EXCISION: ASTROCYTOMA WITH ATYPICAL FEATURES.

SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: Brain, left frontal.

Clinical History and Pre-Op Dx: [REDACTED] year old woman, with past history of difficulty in communicating, probably dysphasic; has a 7 cm, enhancing, cystic left frontal tumor.

GROSS PATHOLOGY:

- A. Received fresh, one fragment of brain tissue, 1.1 cm across. Firm, glistening, tannish-gray. Bisected, in total #1 and 2, frozen tissue #3.

INTRAOPERATIVE CONSULTATION: Brain, left frontal:

- 1. Smears: Glial proliferation and lymphocytes.
- 2. Frozen sections: Glial proliferation, consistent with glioma.

- B. Received fresh, one fragment, 3.5 x 2.2 x 1.8 cm. Firm, homogeneously glistening and tannish-gray, with focal areas of hemorrhage. Serially sectioned, in total #5-9, frozen tissue #4.

INTRAOPERATIVE CONSULTATION: Brain, left frontal:

- 1. Smears: Atypical glial proliferation, consistent with glioma.
- 2. Frozen sections: Glioma.

- C. Received fresh, three fragments, 1.3 cm across in aggregate. Soft, tannish-gray, glistening. In total #10-12.

INTRAOPERATIVE CONSULTATION: Brain, left frontal, smears:

[page 2 of 2]
Astrocytoma with abnormal vessels.

MICROSCOPIC: Portions of a glial neoplastic proliferation that is diffusely and heavily infiltrating the brain parenchyma, including cerebral cortex and white matter. The neoplastic cells have round or ovoid nuclei with prominent single nucleolus. The background is heavily fibrillary, and has a capillary-type vasculature. There are no mitotic figures, microvascular cellular proliferation, or necrosis.

B. Portions of a glial neoplastic proliferation similar to that one described for part A. In here, the neoplasm becomes more cellular, the nuclei become hyperchromatic and moderately pleomorphic, and gemistocytic phenotype is present throughout the tumor. Mitotic figures are present, but are found with difficulty. There is a sparse lymphoid infiltrate, better appreciated in some perivascular areas.

C. Portions of brain diffusely infiltrated by a glial neoplastic proliferation. The neoplasm is similar to that one described for parts

A and B. However, in here the neoplasm is less cellular, although still has the anaplastic nuclear features. Mitotic figures although present, are rather inconspicuous, and microvascular cellular proliferation and necrosis are absent.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP and MIB-1 were performed on sections from block 5 and 6.

The GFAP demonstrates the heavy and diffuse gliofibrillogenesis of the neoplasm. With the MIB-1, proliferative indices of 2% to 3% were determined in the more active areas.

COMMENT: The neoplasm has a heavily fibrillary astrocytic phenotype. There are focal prominent hypercellularity and nuclear anaplasia, very sparse mitotic activity, low MIB-1 proliferation indices, and absent microvascular cellular proliferation and necrosis. These morphological features suggest an anaplastic transformation of a low grade astrocytoma.

Source: NCI Genomic Data Commons file 7a8d8503-1844-46a3-8d5a-81a39e400476 (TCGA-DU-8158.83E22D80-B93F-48CC-9F4F-F6DC0186246C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).